Somatic mutation profile of tumor specimen MP2PRT-PAUVED-TMP1-A (aliquot MP2PRT-PAUVED-TMP1-A-1-0-D-A83P-36) from MP2PRT case MP2PRT-PAUVED, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.0 years (1,474 days).
Specimen MP2PRT-PAUVED-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dd645022-86ae-4307-81b0-61892d8b53a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUVED-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUVED-NB1-A-1-0-D-A83P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b6e28994-12d0-4064-8131-c80222d8a6c7

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1517G>A p.G506E (on ENST00000288602 / NM_001374244.1; = p.G466E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 120/332 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs121913351, CM115083, COSV56057462, COSV56059390, COSV56070593; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FLT3 | c.2503G>T p.D835Y | Missense Mutation (SNP) | VAF 38/301 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913488, COSV54042116, COSV54042636, COSV54045151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FNDC1 | c.5579G>A p.R1860H | Missense Mutation (SNP) | VAF 72/224 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748731303; called by muse, mutect2, varscan2
- GRM7 | c.568C>T p.R190W | Missense Mutation (SNP) | VAF 100/251 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as rs777440646; called by muse, varscan2
- METTL24 | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 145/437 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV58821828; called by muse, varscan2
- PAH | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 82/195 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1466564208, CM135795; called by muse, mutect2, varscan2
- PDPN | c.329C>T p.T110M (on ENST00000621990; = p.T186M on NM_006474.4) | Missense Mutation (SNP) | VAF 78/194 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs368396279; called by muse, mutect2, varscan2
- MROH5 | c.972G>T p.R324S | Missense Mutation (SNP) | VAF 65/154 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTGFRN | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 12/390 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SEMA6B | c.1895G>A p.R632Q | Missense Mutation (SNP) | VAF 21/680 reads (3%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.733); called by muse, mutect2
- OR5I1 | c.51A>G p.L17= | Silent (SNP) | VAF 66/227 reads (29%) | catalogued as rs201769620; called by muse, mutect2, varscan2
- PTPRF | c.2067C>T p.D689= | Silent (SNP) | VAF 193/430 reads (45%) | catalogued as rs369762773; called by muse, mutect2, varscan2
- SEZ6 | c.2214C>T p.C738= | Silent (SNP) | VAF 63/583 reads (11%) | called by muse, mutect2, varscan2
- SNX5 | c.51+149C>T | Intron (SNP) | VAF 197/466 reads (42%) | catalogued as rs540430565; called by muse, mutect2, varscan2
